Surgical pathology report (de-identified scan), TCGA case TCGA-XN-A8T3, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-XN-A8T3-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma, duct NOS
8500/3
Site: Pancreas head
C25.0
9/11/29/14

NATURE OF MATERIAL : PANCREAS

BIOPSY :

MACROSCOPY

- bottle 1 : specimen made of pancreatic head and segment of duodenum . The pancreas measures 6.0 x 4,5x 4,5 cm. The duodenum measuring 15.5 cm in length and diameter 2.5 cm
nIt was noted a head injury in pancreas, measuring 2.4 x 2,2 cm
- bottle 2 : gallbladder measured 12.2 cm length for 2.5 cm in diameter greater .
- bottle 3 : 4 lymph nodes , measuring between 0.2 and 1.0 cm cm in major axes .

MICROSCOPIC

Product of pancreaticoduodenectomy:

- invasive ductal adenocarcinoma localized in cephalic portion of pancreas, moderately differentiated, measuring 2.4 cm.
- foci of intraepithelial pancreatic neoplasms associated with high degree dysplasia / dcis .
- presence of neoplasm infiltration and perineural associated with angiolymphatic embolization .
- lack of infiltration neoplasm duodenal papilla .
- surgical margin committed by pancreatic neoplasms .

No metastasis in lymph nodes examined 15 (0 / 15) .

- Stage: pT2 pN0 .

PATHOLOGISTS

Source: NCI Genomic Data Commons file 92ab5b59-1baf-4209-83d0-e5a39dcd9dd8 (TCGA-XN-A8T3.4B77F18C-2A61-42E5-BF41-05FB9959EB3F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).